Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7781, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7781-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] man with a serum PSA value of 3.57 ng/ml. The patient also had a prostate needle biopsy on [REDACTED] this biopsy revealed: prostatic adenocarcinoma, Gleason score 3+4 = 7 in the left apex and left lateral apex. The patient also has a history of a right total knee arthroplasty, hypertension, hypercholesterolemia, and non-insulin dependent diabetes mellitus.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy and bilateral pelvic lymphadenectomy.

FINAL DIAGNOSIS:

PART 1: RIGHT PELVIC LYMPH NODES, LYMPHADENECTOMY –
TWELVE BENIGN LYMPH NODES (0/12). NO EVIDENCE OF MALIGNANCY.

PART 2: LEFT PELVIC LYMPH NODES, LYMPHADENECTOMY –
FIVE BENIGN LYMPH NODES (0/5). NO EVIDENCE OF MALIGNANCY.

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES, AND BILATERAL DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY –

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE = 3+4=7, WITH A SMALL TERTIARY GLEASON PATTERN 5 COMPONENT (SLIDE 3FF). GLEASON PATTERNS 4/5 COMPONENTS COMPRISE APPROXIMATELY 30% OF THE SAMPLED PROSTATE TUMOR VOLUME.
- B. MAXIMAL TUMOR DIAMETER IS 2.0 CM IN A HISTOLOGIC SECTION (SLIDE 3JJ).
- C. CARCINOMA COMPRISES APPROXIMATELY 15% OF THE EXAMINED PROSTATE GLAND VOLUME.
- D. CARCINOMA IS CONFINED TO THE PROSTATE GLAND, WITH NO EXTRACAPSULAR EXTENSION IDENTIFIED.
- E. FOCAL PERINEURAL INVASION IDENTIFIED (SLIDE 3Q).
- F. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. BENIGN BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA.
- H. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA.
- I. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASIA.
- J. NON-NEOPLASTIC PROSTATE TISSUE WITH MILD NODULAR HYPERPLASIA, FOCAL GLANDULAR ATROPHY, AND FOCAL CHRONIC INFLAMMATION.
- K. TNM PATHOLOGIC STAGE = T2c, N0, MX.
- L. HISTOLOGIC GRADE G3-4 (See synoptic).

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 3.57
INVASIVE CA IDENTIFIED?:	No
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	30%
WEIGHT OF PROSTATE:	51.83gm
TUMOR SIZE:	Maximum dimension: 2.0 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Unknown
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	17
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Comment: A small tertiary Gleason pattern 5 carcinoma component is present.

Source: NCI Genomic Data Commons file b7c6a47b-31bf-45b2-85c0-b0958273e62d (TCGA-EJ-7781.3582FF42-09F7-4FFB-9421-60F3CBA1FF28.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).